Gene-level copy-number profile of tumor specimen ALCH-B3JP-TTP1-A from ALCHEMIST case ALCH-B3JP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.0 years (23,729 days).
Specimen ALCH-B3JP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a9734bee-4883-4956-9376-4200617e8dfe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3JP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/aff76751-3ac5-42f9-b278-bdf441436138

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 858; copy number 2: 19,508; copy number 3: 18,995; copy number 4: 12,751; copy number 5: 4,286; copy number 6: 577; copy number 7: 861; copy number 8: 57; copy number 9: 81; copy number 10: 53; copy number 11: 12; copy number 12: 17; copy number 14: 12; copy number 15: 735; copy number 17: 33; copy number 26: 29; copy number 29: 1; copy number 67: 1; copy number 129: 4; copy number 135: 3.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr10:47,689,707–48,060,016, 11 genes: SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7.
- chr17:1,022,476–1,022,559, 1 gene (within-gene range 0–2): MIR3183.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,899 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,760,617–159,897,366, 73 genes, copy number 14–15 (broad region; genes not listed).
- chr3:164,978,898–198,123,232, 620 genes, copy number 15–17 (broad region; genes not listed).
- chr4:190,041,342–190,092,279, 12 genes, copy number 7: AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:180,967,189–181,006,727, 4 genes, copy number 7: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:46,634,614–48,108,736, 19 genes, copy number 10: HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1.
- chr7:57,599,794–57,837,046, 22 genes, copy number 10: NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:102,285,091–102,426,676, 9 genes, copy number 8 (within-gene range 5–8): SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2.
- chr7:129,953,234–131,496,632, 47 genes, copy number 8 (within-gene range 5–8): AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS.
- chr9:40,223,285–40,266,845, 2 genes, copy number 15: ANKRD20A2P, RNU6-1269P.
- chr12:66,767–40,106,089, 859 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr13:57,204,379–57,204,799, 1 gene, copy number 11: MTCO2P3.
- chr14:105,583,731–105,588,395, 1 gene, copy number 7: IGHA2.
- chr18:23,689,453–23,956,222, 1 gene, copy number 7 (within-gene range 5–7): LAMA3.
- chr18:24,534,551–24,708,542, 1 gene, copy number 9 (within-gene range 4–9): LINC01915.
- chr19:37,371,061–40,576,464, 163 genes, copy number 9–15 (broad region; genes not listed).
- chr19:43,192,702–43,269,530, 3 genes, copy number 9: PSG4, CEACAMP10, PSG9.
- chr19:52,297,169–52,345,229, 2 genes, copy number 7 (within-gene range 4–7): ZNF480, AC010320.4.
- chr21:7,744,962–8,701,562, 29 genes, copy number 26: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr21:9,902,344–13,427,773, 27 genes, copy number 9–135 (within-gene range 5–135): RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3.
- chr22:18,733,914–18,843,399, 4 genes, copy number 10: FAM230E, GGT3P, AC008132.2, E2F6P1.

Autosomal genes at a single copy (total copy number 1): 852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
